Somatic mutation profile of tumor specimen ALCH-B36R-TTP1-A (aliquot ALCH-B36R-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B36R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 71.2 years (25,994 days).
Specimen ALCH-B36R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70b74976-b010-4ff8-a059-c613f4537497.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36R-NB1-A (Blood Derived Normal), aliquot ALCH-B36R-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c776d87-13cb-4531-bdae-5e85cbea58da

The open-access MAF lists 255 somatic variants for this specimen: 167 protein-altering or splice-affecting, 65 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 65, Intron 10, RNA 5, Nonsense Mutation 5, 5'UTR 3, Frame Shift Del 2, 3'UTR 2, 3'Flank 2, Splice Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>G p.R282G | Missense Mutation (SNP) | VAF 77/308 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM1 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201411317; called by muse, mutect2, varscan2
- ADCY10 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774492801; called by muse, mutect2, varscan2
- ADGB | c.2035C>G p.L679V | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs1329791322, COSV58858719; called by muse, mutect2
- AHCTF1 | c.4180G>A p.G1394R (on ENST00000366508; = p.G1368R on NM_015446.5) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as rs1404491944, COSV58246195; called by muse, mutect2, varscan2
- AIRE | c.1412G>C p.R471P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs373237600; called by muse, mutect2, varscan2
- AMER1 | c.1937G>C p.R646P | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.079); catalogued as rs147754688, COSV100366837; called by muse, mutect2, varscan2
- ANKFN1 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.85); catalogued as rs1448778167, COSV59442211; called by muse, mutect2, varscan2
- CAMTA1 | c.4333G>T p.A1445S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs1375385559; called by muse, mutect2
- CC2D1B | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as COSV52561834; called by muse, mutect2
- CD1C | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV63806816; called by muse, mutect2, varscan2
- DCAF4L2 | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60476978, COSV60484022; called by muse, mutect2
- GIMAP4 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748613520, COSV55431046, COSV55433796; called by muse, mutect2, varscan2
- GLI3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 101/377 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1025335707, COSV67886291; called by muse, mutect2, varscan2
- GPR137C | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.41); catalogued as rs775052093; called by muse, mutect2
- H3C2 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); catalogued as rs757910438; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1485A>C p.R495S | Missense Mutation (SNP) | VAF 99/619 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); catalogued as COSV56258083; called by muse, mutect2, varscan2
- KCNC4 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as rs777571978, COSV63924913; called by muse, mutect2, varscan2
- KCNK18 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs754574739; called by muse, mutect2
- KMT2D | c.10938del p.P3647Lfs*11 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as COSV56482210; called by mutect2, varscan2
- LAMA1 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.591); catalogued as COSV101057501; called by muse, mutect2, varscan2
- LRRC7 | c.2234G>A p.G745E (on ENST00000651989 / NM_001370785.2; = p.G712E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs773021847, COSV50408899; called by muse, mutect2, varscan2
- MAML2 | c.3145C>T p.L1049F | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as COSV101594112; called by muse, mutect2, varscan2
- MCHR1 | c.917C>A p.S306Y | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); catalogued as rs772358457, COSV50762422; called by muse, mutect2, varscan2
- MDGA2 | c.1918G>T p.V640L (on ENST00000399232 / NM_001113498.2; = p.V342L on NM_182830.4) | Missense Mutation (SNP) | VAF 41/380 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as rs1477036326; called by muse, mutect2, varscan2
- MED23 | c.2864A>G p.Y955C | Missense Mutation (SNP) | VAF 45/385 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183483337; called by muse, mutect2, varscan2
- MEOX2 | c.234C>A p.H78Q | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1562620056; called by mutect2, varscan2
- MROH5 | c.3892C>T p.R1298W | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs143215537; called by muse, mutect2, varscan2
- MTM1 | c.721C>A p.R241S | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM970993, COSV100080338; called by muse, mutect2, varscan2
- NAV3 | c.4792C>A p.L1598I | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV57080071; called by muse, mutect2, varscan2
- NLRP8 | c.1045C>G p.P349A | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV52587927, COSV52594570; called by muse, mutect2, varscan2
- OR10Z1 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs750887023; called by muse, mutect2, varscan2
- OR14A16 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV62927523; called by muse, mutect2
- OR2C1 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs772630283; called by muse, mutect2, varscan2
- OR4D11 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); catalogued as rs758509200; called by muse, mutect2, varscan2
- OR4P4 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV58923181; called by muse, mutect2
- OR5L2 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65723904, COSV65725055; called by muse, mutect2, varscan2
- OR8J1 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1161398923; called by muse, mutect2
- OTUD5 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs1557055625; called by muse, mutect2, varscan2
- PCDHGA12 | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52751518; called by muse, mutect2, varscan2
- PHKA1 | c.1459G>T p.G487* | Nonsense Mutation (SNP) | VAF 50/418 reads (12%) | catalogued as COSV59808562; called by muse, mutect2, varscan2
- PLSCR5 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV71649163; called by muse, mutect2, varscan2
- POTEE | c.2659G>T p.D887Y | Missense Mutation (SNP) | VAF 43/507 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs747787553, COSV100387672; called by muse, mutect2
- PRAF2 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.133); catalogued as COSV59875369; called by mutect2, varscan2
- PRRC2B | c.3793G>T p.A1265S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778987964, COSV61933540; called by muse, mutect2, varscan2
- PSG6 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 74/506 reads (15%) | catalogued as rs368412072; called by muse, mutect2, varscan2
- PTPRD | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.962); catalogued as COSV100644720; called by muse, mutect2, varscan2
- SECTM1 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs1185116592; called by muse, mutect2, varscan2
- SELE | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as COSV60975249; called by muse, mutect2
- SENP1 | c.10A>G p.I4V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as rs1467048327; called by muse, mutect2
- SLC35B3 | c.919G>T p.G307* | Nonsense Mutation (SNP) | VAF 31/208 reads (15%) | catalogued as rs1427570469; called by muse, mutect2, varscan2
- SMC1A | c.2695G>C p.G899R | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.878); catalogued as COSV59127929, COSV59129615; called by muse, mutect2, varscan2
- STX18 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.73); catalogued as rs755050963, COSV60373614; called by muse, mutect2
- THEMIS | c.1592T>C p.L531P | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs376358136; called by muse, mutect2, varscan2
- TRAT1 | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1329977099; called by muse, mutect2, varscan2
- TRMT2B | c.92G>T p.W31L | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV100105407; called by muse, mutect2
- VN1R4 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV60804842; called by muse, mutect2
- ZBTB37 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV62933739; called by muse, mutect2, varscan2
- ZNF549 | c.1706G>A p.R569H (on ENST00000376233 / NM_001199295.2; = p.R556H on NM_153263.2) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs752950042, COSV53725601; called by muse, mutect2, varscan2
- ADAMTS20 | c.4891C>A p.P1631T | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.051); called by muse, mutect2
- ADH6 | c.931T>C p.S311P | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AHNAK | c.8806G>A p.D2936N | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- ALOX12 | c.737C>G p.S246C | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ALX4 | c.1161C>A p.D387E | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- ANO4 | c.2180T>C p.V727A (on ENST00000392977 / NM_001286615.2; = p.V692A on NM_178826.4) | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATP13A3 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ATRNL1 | c.2980G>T p.D994Y | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ATRX | c.1994G>A p.R665K | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- BBS9 | c.962A>T p.K321M | Missense Mutation (SNP) | VAF 71/355 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCN2 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- CDHR3 | c.1967A>T p.N656I | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK19 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); called by mutect2, varscan2
- CFH | c.263C>G p.P88R | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CHI3L2 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CLCA4 | c.1454A>G p.Q485R | Missense Mutation (SNP) | VAF 50/383 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CLGN | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CNTN3 | c.217A>T p.M73L | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- COBL | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CSMD2 | c.9460G>T p.V3154F | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CTNNA3 | c.1753C>A p.Q585K | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.063); called by muse, mutect2
- DAAM2 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- DCHS1 | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX38 | c.2564G>C p.G855A | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EBF3 | c.1724C>G p.P575R (on ENST00000355311 / NM_001375392.1; = p.P530R on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- EML5 | c.3436G>T p.A1146S | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- FAT1 | c.9515T>C p.F3172S | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXL6 | c.389C>A p.A130E | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- FIGN | c.1497A>C p.K499N | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by mutect2, varscan2
- FOXO4 | c.85C>A p.R29S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GCA | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- GDI1 | c.1149C>G p.I383M | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.843); called by muse, mutect2
- GPR119 | c.533T>G p.M178R | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GRIA3 | c.866G>T p.R289M | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GRIA3 | c.867G>T p.R289S | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HBZ | c.362A>T p.E121V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HDAC6 | c.1664A>T p.K555I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HHIPL1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- HHLA1 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 57/337 reads (17%) | called by muse, mutect2, varscan2
- IARS2 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IFRD2 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- IMPG2 | c.1240-2dup p.X414_splice | Splice Site (INS) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- IRS4 | c.2378C>G p.P793R | Missense Mutation (SNP) | VAF 55/380 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ITSN1 | c.74A>C p.H25P | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF4A | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KLF1 | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP16-1 | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- LNX2 | c.448A>T p.R150W | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- LRRK2 | c.6124G>A p.E2042K | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MACF1 | c.10567A>G p.S3523G | Missense Mutation (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- MAP10 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MDC1 | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYL2 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MYO10 | c.3058A>G p.T1020A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- NAV3 | c.4791C>A p.H1597Q | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- NDRG2 | c.938G>A p.G313D (on ENST00000298687 / NM_001354570.1; = p.G299D on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLGN4X | c.2245C>T p.H749Y | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- NLRP9 | c.2199C>A p.D733E | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NWD2 | c.3859A>C p.N1287H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); called by muse, mutect2
- OR12D3 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR8U1 | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- OTUD5 | c.450G>T p.K150N | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- OVCH2 | c.933C>G p.C311W | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- PARP10 | c.1123G>T p.G375W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PBXIP1 | c.2008G>T p.V670L | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PCDHGA1 | c.837C>A p.Y279* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- PDE1C | c.1337C>G p.T446S | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- PLOD1 | c.1736G>T p.W579L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- POSTN | c.2161A>G p.T721A | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- PPME1 | c.781G>C p.D261H | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- PRAMEF4 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- PRELP | c.429G>C p.Q143H | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- PRKAR1B | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PRSS35 | c.772C>A p.H258N | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- RIMBP2 | c.1543C>A p.P515T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.8346G>C p.M2782I | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- SATL1 | c.1181T>A p.I394N (on ENST00000395409; = p.I581N on NM_001012980.2) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SCFD2 | c.511C>G p.P171A | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SFMBT1 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- SHCBP1 | c.690G>A p.L230= | Splice Region (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- SLC4A7 | c.2860G>C p.D954H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLCO1A2 | c.1669G>C p.V557L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2
- SNX8 | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPACA5B | c.258C>A p.D86E | Missense Mutation (SNP) | VAF 40/569 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- SUPT20HL1 | c.1682C>A p.A561D | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.065); called by muse, varscan2
- SYPL2 | c.381C>G p.F127L | Missense Mutation (SNP) | VAF 42/323 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAF1 | c.5478G>T p.Q1826H (on ENST00000373790 / NM_138923.4; = p.Q1847H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- TBC1D9 | c.2449G>A p.V817M | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.029); called by muse, mutect2
- TLR7 | c.1516T>C p.F506L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TMPRSS4 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2
- TNKS1BP1 | c.4097G>T p.G1366V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPR | c.4291A>G p.I1431V | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TRGJP1 | c.37A>T p.T13S | Missense Mutation (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- TRIM49B | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- TRIM71 | c.2094del p.Q699Sfs*10 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- TRPM2 | c.2511C>G p.F837L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTN | c.69107C>A p.T23036N (on ENST00000591111; = p.T15612N on NM_003319.4) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- TTN | c.52739T>A p.I17580N (on ENST00000591111; = p.I10156N on NM_003319.4) | Missense Mutation (SNP) | VAF 54/506 reads (11%) | PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- USP9X | c.4927G>T p.V1643F | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- UTRN | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZDBF2 | c.4544G>A p.G1515E | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZFHX4 | c.8649C>A p.D2883E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ZFP62 | c.1363G>C p.G455R (on ENST00000502412 / NM_001377944.1; = p.G422R on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF134 | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF160 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ZNF565 | c.971G>A p.C324Y (on ENST00000355114; = p.C284Y on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF704 | c.52A>T p.M18L | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF75D | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ABCA8 | c.4026G>T p.V1342= | Silent (SNP) | VAF 14/129 reads (11%) | called by muse, mutect2, varscan2
- AC100868.1 | c.1122C>T p.L374= | Silent (SNP) | VAF 34/458 reads (7%) | called by muse, mutect2
- ADAM29 | c.777A>T p.V259= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- ALDH1B1 | c.84C>T p.P28= | Silent (SNP) | VAF 12/61 reads (20%) | called by muse, varscan2
- ANKRD34C | c.432C>G p.A144= | Silent (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- ATRX | c.324T>A p.S108= | Silent (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- B4GALNT4 | c.2820G>A p.A940= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs778813288, COSV100327751; called by muse, mutect2, varscan2
- BAZ1A | c.3978A>C p.T1326= | Silent (SNP) | VAF 40/365 reads (11%) | called by muse, mutect2, varscan2
- BBS7 | c.1488A>G p.R496= | Silent (SNP) | VAF 32/178 reads (18%) | catalogued as rs1484511643; called by muse, mutect2, varscan2
- C18orf54 | c.136A>C p.R46= | Silent (SNP) | VAF 54/401 reads (13%) | called by muse, mutect2, varscan2
- CDIPT | c.396G>T p.R132= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- CSMD3 | c.7209T>C p.N2403= (on ENST00000297405 / NM_001363185.1; = p.N2299= on NM_052900.3) | Silent (SNP) | VAF 65/573 reads (11%) | called by muse, mutect2, varscan2
- CTR9 | c.1857C>T p.T619= | Silent (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- CUL4A | c.279C>G p.L93= | Silent (SNP) | VAF 372/621 reads (60%) | catalogued as rs1475824528; called by muse, mutect2, varscan2
- CYSLTR2 | c.894C>A p.A298= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- DES | c.531C>T p.D177= | Silent (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- DLGAP3 | c.801G>A p.L267= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- DNAH11 | c.6639C>A p.L2213= | Silent (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- DRC7 | c.1821C>T p.R607= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as rs968736695, COSV61054031; called by muse, mutect2, varscan2
- ELK1 | c.381C>A p.V127= | Silent (SNP) | VAF 18/185 reads (10%) | called by muse, mutect2
- EMID1 | c.1008C>T p.H336= | Silent (SNP) | VAF 13/144 reads (9%) | called by muse, mutect2
- FAM135B | c.3492G>A p.L1164= | Silent (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- FIBCD1 | c.1248G>T p.T416= | Silent (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- GABRA3 | c.723C>T p.N241= | Silent (SNP) | VAF 24/245 reads (10%) | called by muse, mutect2
- HBQ1 | c.36C>A p.R12= | Silent (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- ICE1 | c.5229G>T p.G1743= | Silent (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2, varscan2
- IGHV3-38 | c.54G>A p.Q18= | Silent (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- INSYN2A | c.1437T>G p.L479= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- KALRN | c.6987C>A p.I2329= (on ENST00000360013 / NM_001024660.4; = p.I632= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- KLF1 | c.1050C>T p.R350= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV99322422; called by muse, mutect2, varscan2
- LATS2 | c.1503G>T p.P501= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- MPL | c.1158C>T p.H386= | Silent (SNP) | VAF 27/217 reads (12%) | called by muse, mutect2, varscan2
- MYO3B | c.2076C>T p.F692= | Silent (SNP) | VAF 24/204 reads (12%) | catalogued as rs370816094; called by muse, mutect2, varscan2
- NALCN | c.1953A>T p.S651= | Silent (SNP) | VAF 51/224 reads (23%) | called by muse, mutect2, varscan2
- NAT10 | c.1203A>T p.L401= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- NBEA | c.3840C>A p.I1280= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV59805329; called by muse, mutect2
- NBPF6 | c.214C>T p.L72= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1227323117, COSV53996018; called by mutect2, varscan2
- NOM1 | c.2181C>T p.F727= | Silent (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- OR6K2 | c.942C>T p.S314= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs912488831, COSV62743100, COSV62744258; called by muse, varscan2
- PCDH17 | c.1623C>T p.N541= | Silent (SNP) | VAF 49/212 reads (23%) | catalogued as rs1056370797; called by muse, mutect2, varscan2
- PCDHGA9 | c.489C>T p.G163= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as COSV53892738; called by muse, mutect2, varscan2
- PCLO | c.3549A>G p.E1183= | Silent (SNP) | VAF 27/158 reads (17%) | called by muse, mutect2, varscan2
- POLR3B | c.1593C>G p.L531= | Silent (SNP) | VAF 51/368 reads (14%) | called by muse, mutect2, varscan2
- PPP1R42 | c.929G>A p.*310= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- PPP2R1B | c.1761C>T p.V587= | Silent (SNP) | VAF 20/199 reads (10%) | called by muse, mutect2, varscan2
- PRICKLE3 | c.670C>T p.L224= | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- RELB | c.1338G>T p.L446= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs762884186, COSV55512172; called by muse, mutect2, varscan2
- RIMBP2 | c.1545C>A p.P515= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2
- RTL9 | c.3474C>T p.A1158= | Silent (SNP) | VAF 25/142 reads (18%) | called by muse, mutect2, varscan2
- SCN10A | c.588C>G p.V196= | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- SERINC4 | c.1209G>A p.A403= | Silent (SNP) | VAF 22/128 reads (17%) | catalogued as rs1193921795, COSV51049453; called by muse, varscan2
- SLC13A3 | c.1083G>C p.P361= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV99286770; called by muse, mutect2, varscan2
- SLC9A9 | c.1320G>A p.L440= | Silent (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- SLIT2 | c.4345C>A p.R1449= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV56570642; called by muse, mutect2
- SLITRK1 | c.354C>A p.I118= | Silent (SNP) | VAF 48/371 reads (13%) | catalogued as rs1310801355, COSV65676960; called by muse, mutect2, varscan2
- SLITRK5 | c.1128C>A p.T376= | Silent (SNP) | VAF 41/212 reads (19%) | catalogued as COSV61522211; called by muse, mutect2, varscan2
- SMYD3 | c.1101C>T p.P367= (on ENST00000490107 / NM_001375962.1; = p.P308= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as rs148679457; called by muse, mutect2, varscan2
- TAF1 | c.2688G>A p.E896= (on ENST00000373790 / NM_138923.4; = p.E917= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- TET1 | c.3123A>G p.R1041= | Silent (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- TNKS1BP1 | c.4098G>T p.G1366= | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- TRPA1 | c.2457G>T p.V819= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- TRPT1 | c.247A>C p.R83= (on ENST00000317459 / NM_001160393.1; = p.R34= on NM_031472.4) | Silent (SNP) | VAF 10/111 reads (9%) | called by muse, mutect2
- VIRMA | c.3306C>T p.I1102= | Silent (SNP) | VAF 35/317 reads (11%) | called by muse, mutect2, varscan2
- WASHC2A | c.1734A>G p.E578= | Silent (SNP) | VAF 33/177 reads (19%) | catalogued as rs1248646134; called by muse, mutect2, varscan2
- ZDHHC18 | c.840G>A p.L280= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV65145785; called by muse, mutect2, varscan2
- AC068633.1 | n.19A>G | RNA (SNP) | VAF 8/75 reads (11%) | catalogued as rs1298105875; called by muse, mutect2, varscan2
- AIP | c.468+25C>T | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.5385+123C>T | Intron (SNP) | VAF 20/184 reads (11%) | called by mutect2, varscan2
- BMS1P15 | n.343G>A | RNA (SNP) | VAF 20/338 reads (6%) | catalogued as rs754019124; called by muse, mutect2
- C3orf85 | c.183+13G>C | Intron (SNP) | VAF 34/245 reads (14%) | called by muse, mutect2, varscan2
- COPS8 | c.503-58G>T | Intron (SNP) | VAF 48/364 reads (13%) | called by muse, mutect2, varscan2
- DLX4 | c.284-46C>T | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- ITGA5 | c.-2C>T | 5'UTR (SNP) | VAF 12/67 reads (18%) | catalogued as rs1244519143; called by muse, mutect2, varscan2
- MIR1302-9 | chr9:35216 G>C | 3'Flank (SNP) | VAF 8/74 reads (11%) | called by mutect2, varscan2
- MIR22 | chr17:1716596 C>T | 5'Flank (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- MRPS31 | chr13:40727842 C>T | 3'Flank (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- NRG3 | c.823+1916T>A | Intron (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2
- PDE4B | c.477-192G>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- PITRM1 | c.2917+39C>T | Intron (SNP) | VAF 33/267 reads (12%) | catalogued as rs1470775387; called by muse, mutect2, varscan2
- SGCA | c.983+1154G>T | Intron (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- SLC7A5P2 | n.151A>T | RNA (SNP) | VAF 10/141 reads (7%) | catalogued as rs774130689; called by muse, mutect2
- SNORD115-44 | n.81C>T | RNA (SNP) | VAF 38/298 reads (13%) | catalogued as rs777125124; called by muse, mutect2, varscan2
- STXBP1 | c.1702+1860C>A | Intron (SNP) | VAF 55/333 reads (17%) | called by muse, mutect2, varscan2
- THY1 | c.*79T>A | 3'UTR (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- TIA1 | c.-10A>T | 5'UTR (SNP) | VAF 20/75 reads (27%) | catalogued as rs1283279454; called by muse, mutect2, varscan2
- UBTFL2 | n.802C>A | RNA (SNP) | VAF 45/291 reads (15%) | called by muse, mutect2, varscan2
- UQCRB | c.*2418C>T | 3'UTR (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- ZSWIM8 | c.-193G>A | 5'UTR (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
